CCDI case PBBLXV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/52f208ab-965c-42ae-9793-29cd4a0b7458

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 17.1 years (6,231 days).

Biospecimens (3 samples)
- Sample 0DC9UQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DC9UX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DC9V0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
